Somatic mutation profile of tumor specimen TCGA-02-0003-01A (aliquot TCGA-02-0003-01A-01D-1490-08) from TCGA case TCGA-02-0003, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.2 years (18,341 days).
Specimen TCGA-02-0003-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 149ce67d-c03d-471f-9524-41bf5288c239.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-0003-10A (Blood Derived Normal), aliquot TCGA-02-0003-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fd169e5-a79b-405f-8c4e-b20a03d8a4a9

The open-access MAF lists 47 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 39, Silent 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 46/106 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.534C>A p.H178Q | Missense Mutation (SNP) | VAF 51/132 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526001, CM1313554, COSV52741277, COSV53120340, COSV53165113, COSV53624003; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.3980A>G p.D1327G | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55217305; called by muse, mutect2, varscan2
- ANAPC4 | c.1005G>T p.Q335H | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV59544624; called by muse, mutect2, varscan2
- AUTS2 | c.3508G>A p.V1170M | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.104); catalogued as rs757165955, COSV61409582; called by muse, mutect2, varscan2
- BTBD11 | c.2308G>A p.E770K (on ENST00000280758 / NM_001018072.2; = p.E307K on NM_001017523.2) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1415961019, COSV55022441, COSV55024035; called by muse, mutect2, varscan2
- DZIP1L | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 122/252 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as COSV59521603; called by muse, mutect2, varscan2
- EGFR | c.1859G>A p.C620Y | Missense Mutation (SNP) | VAF 1515/3439 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150899403, COSV51809225; called by muse, mutect2, varscan2
- ELMO1 | c.982C>G p.R328G | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60294952, COSV60308508; called by muse, mutect2, varscan2
- EML1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs764781997, COSV51746801; called by muse, mutect2, varscan2
- EPHA7 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1465346253, COSV65168785; called by muse, mutect2, varscan2
- ESYT3 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs199999624, COSV56681795; called by muse, mutect2, varscan2
- HOXB1 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53317592; called by muse, mutect2, varscan2
- HRH2 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 190/467 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs568716866, COSV51573019; called by muse, mutect2, varscan2
- KIAA0319 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.877); catalogued as rs137950263; called by muse, mutect2, varscan2
- KIF27 | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs3199677; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs761312968, COSV51721612; called by muse, mutect2
- MTERF2 | c.638T>C p.L213S | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53527817; called by muse, mutect2, varscan2
- MTX3 | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV72512358; called by muse, mutect2, varscan2
- MUC17 | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 256/941 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV60291797; called by muse, mutect2, varscan2
- NAALAD2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs915139665, COSV58958529; called by muse, mutect2, varscan2
- NLRP5 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs754281729, COSV66763265; called by mutect2, varscan2
- NPRL2 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 109/399 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602369; called by muse, mutect2, varscan2
- OBSL1 | c.3488A>G p.N1163S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.366); catalogued as COSV54707010; called by muse, mutect2, varscan2
- PANX3 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1288712481, COSV52512566; called by muse, mutect2, varscan2
- PKDREJ | c.2438G>T p.S813I | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV53549940; called by muse, mutect2, varscan2
- PODNL1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs142083249; called by muse, mutect2, varscan2
- POTEA | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.148); catalogued as rs1231215026; called by muse, mutect2, varscan2
- SHPRH | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV51611677; called by muse, mutect2, varscan2
- SLC11A1 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as rs769343240, COSV51917593; called by muse, mutect2, varscan2
- SLC2A14 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as rs778525180, COSV61585472; called by muse, mutect2, varscan2
- SLC2A3 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs200481428, COSV50000303; called by muse, mutect2, varscan2
- SLC39A7 | c.707T>C p.F236S | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs763477698, COSV63399790; called by muse, mutect2, varscan2
- SPATA22 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as COSV52153000; called by muse, mutect2, varscan2
- TACC2 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.153); catalogued as rs540521848, COSV57745865; called by muse, mutect2, varscan2
- TPM3 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 126/275 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55136839; called by muse, mutect2, varscan2
- TSHZ2 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs779892655, COSV61589413; called by muse, mutect2, varscan2
- ZNF583 | c.372T>G p.S124R | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52403015; called by muse, mutect2, varscan2
- CLEC3B | c.276C>T p.H92= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs1458527599, COSV56109926; called by muse, mutect2, varscan2
- CLHC1 | c.393G>T p.S131= | Silent (SNP) | VAF 53/109 reads (49%) | catalogued as COSV63427189; called by muse, mutect2, varscan2
- DNAH5 | c.11940G>A p.E3980= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs377018163; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM83F | c.1056C>T p.G352= | Silent (SNP) | VAF 47/89 reads (53%) | catalogued as rs763939183, COSV61000445; called by muse, mutect2, varscan2
- ILF3 | c.576C>T p.N192= | Silent (SNP) | VAF 82/210 reads (39%) | catalogued as COSV51557674; called by muse, mutect2, varscan2
- JAKMIP3 | c.2169C>T p.D723= | Silent (SNP) | VAF 65/82 reads (79%) | catalogued as rs763531628, COSV53824516; called by muse, mutect2, varscan2
- MYH6 | c.3871C>A p.R1291= | Silent (SNP) | VAF 92/206 reads (45%) | catalogued as COSV62451770, COSV62454816; called by muse, mutect2, varscan2
- WDR72 | c.1026T>A p.S342= | Silent (SNP) | VAF 53/61 reads (87%) | catalogued as COSV64748574; called by muse, mutect2, varscan2
